Somatic mutation profile of tumor specimen TCGA-HZ-8315-01A (aliquot TCGA-HZ-8315-01A-11D-2396-08) from TCGA case TCGA-HZ-8315, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.3 years (19,839 days).
Specimen TCGA-HZ-8315-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb7a8221-adb9-4140-a41a-2d2c2f6ecaec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-8315-10A (Blood Derived Normal), aliquot TCGA-HZ-8315-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51952aee-a698-4be2-970d-b5e9e8b5972b

The open-access MAF lists 66 somatic variants for this specimen: 47 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SCN1A | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 73/579 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750209664, COSV57692437; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 35/243 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADNP | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 131/1068 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV100823643; called by muse, mutect2, varscan2
- AMY2A | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 122/801 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101340618; called by muse, mutect2, varscan2
- APOB | c.12625G>A p.G4209R | Missense Mutation (SNP) | VAF 51/389 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV99263650; called by muse, mutect2, varscan2
- C1S | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.065); catalogued as COSV100196380; called by muse, mutect2, varscan2
- CACNA1B | c.4123G>A p.V1375M | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs777421980, COSV53152730; called by muse, mutect2, varscan2
- CADPS | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 60/502 reads (12%) | catalogued as COSV99335987; called by muse, mutect2, varscan2
- CLEC18A | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.579); catalogued as COSV99846842; called by muse, mutect2
- COL16A1 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372854054; called by muse, mutect2, varscan2
- CYLC1 | c.1213T>G p.F405V | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100254062; called by muse, mutect2
- DCHS1 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 76/553 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs1388707336, COSV55033080; called by muse, mutect2, varscan2
- DDX31 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 85/791 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64650270, COSV64650741; called by muse, mutect2, varscan2
- DOCK7 | c.5430T>G p.D1810E (on ENST00000635253 / NM_001367561.1; = p.D1779E on NM_033407.3) | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV99222883; called by muse, mutect2, varscan2
- HECW2 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.027); catalogued as COSV99645913; called by muse, mutect2, varscan2
- KCNB1 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 109/795 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368043123, COSV65568219; called by muse, mutect2, varscan2
- KCNC3 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs779810264, COSV100979173; called by muse, mutect2, varscan2
- LIN7A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs779467317, COSV54018072; called by muse, mutect2
- MAN1B1 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 70/450 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs138090529; called by muse, mutect2, varscan2
- MTM1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1557415137, COSV60336381; called by muse, mutect2, varscan2
- MUC16 | c.36745C>T p.R12249C | Missense Mutation (SNP) | VAF 110/692 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as rs760969863, COSV101198191; called by muse, mutect2, varscan2
- MUC16 | c.33664T>C p.F11222L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.11); catalogued as COSV101198193; called by muse, mutect2
- MVP | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62421711; called by muse, mutect2, varscan2
- MYBPC1 | c.2002A>G p.R668G (on ENST00000550270 / NM_206820.2; = p.R693G on NM_002465.4) | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100637755; called by muse, mutect2, varscan2
- NCKAP1L | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV53207958; called by muse, mutect2, varscan2
- NLGN3 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62441730; called by muse, mutect2, varscan2
- ORC1 | c.1766G>A p.G589D | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV100856586; called by muse, mutect2
- PLTP | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 76/556 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100819051; called by muse, mutect2, varscan2
- PTGR2 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 71/603 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99966252; called by muse, mutect2, varscan2
- RASA3 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs756024760, COSV100479837; called by muse, mutect2
- RBBP7 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 70/574 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101198266; called by muse, varscan2
- SLC22A7 | c.1079_1081del p.S360del (on ENST00000372585 / NM_153320.2; = p.S358del on NM_006672.3) | In Frame Del (DEL) | VAF 35/306 reads (11%) | catalogued as rs1394976817; called by mutect2, pindel, varscan2
- SPOP | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 160/1121 reads (14%) | catalogued as COSV100753177; called by muse, mutect2, varscan2
- STK31 | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 66/545 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV63455699; called by muse, mutect2, varscan2
- TCTEX1D1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 78/625 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV99258908; called by muse, mutect2, varscan2
- THOC5 | c.1520G>T p.C507F | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.549); catalogued as COSV100803455; called by muse, mutect2, varscan2
- THSD7B | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55677748, COSV55742163; called by muse, mutect2, varscan2
- TM7SF3 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1027973629, COSV100544635; called by muse, mutect2, varscan2
- TMEM208 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 78/613 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as COSV99263853; called by muse, mutect2, varscan2
- ZNF320 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 66/495 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101206839; called by muse, mutect2, varscan2
- ZNF43 | c.2162T>C p.L721P | Missense Mutation (SNP) | VAF 59/380 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1247604727, COSV100731691; called by muse, mutect2, varscan2
- ZNF483 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 65/466 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV100492649; called by muse, mutect2, varscan2
- ACVR2A | c.373+2dup p.X125_splice | Splice Site (INS) | VAF 157/1217 reads (13%) | called by mutect2, pindel, varscan2
- ARID1A | c.1780del p.Q594Sfs*25 | Frame Shift Del (DEL) | VAF 105/944 reads (11%) | called by mutect2, pindel, varscan2
- SLC4A1 | c.2096del p.G699Afs*11 | Frame Shift Del (DEL) | VAF 41/287 reads (14%) | called by mutect2, pindel, varscan2
- SMAD4 | c.1139+1_1139+2del p.X380_splice | Splice Site (DEL) | VAF 29/284 reads (10%) | called by mutect2, pindel
- ABCB7 | c.1914G>A p.S638= (on ENST00000373394 / NM_001271696.3; = p.S639= on NM_004299.6) | Silent (SNP) | VAF 42/317 reads (13%) | catalogued as rs371978286, COSV53718720; called by muse, mutect2, varscan2
- APOH | c.21C>T p.I7= | Silent (SNP) | VAF 23/204 reads (11%) | catalogued as COSV99235557; called by muse, mutect2, varscan2
- ARHGAP6 | c.2895C>T p.N965= (on ENST00000337414 / NM_013427.3; = p.N762= on NM_013423.3) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100272306; called by muse, mutect2
- CHST8 | c.111C>T p.L37= | Silent (SNP) | VAF 60/643 reads (9%) | catalogued as rs150945646; called by muse, mutect2
- CSAD | c.1464G>A p.R488= (on ENST00000444623 / NM_001244705.2; = p.R515= on NM_015989.5) | Silent (SNP) | VAF 33/251 reads (13%) | catalogued as COSV99914499; called by muse, mutect2, varscan2
- CYP26B1 | c.510C>T p.R170= | Silent (SNP) | VAF 81/568 reads (14%) | catalogued as rs145145054; called by muse, mutect2, varscan2
- DCAF12L2 | c.1245C>T p.D415= | Silent (SNP) | VAF 129/939 reads (14%) | catalogued as rs753659766, COSV63581096; called by muse, mutect2, varscan2
- DNMT1 | c.2817G>A p.V939= | Silent (SNP) | VAF 23/240 reads (10%) | catalogued as COSV61581221; called by muse, mutect2
- IGHA2 | c.345G>A p.S115= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs782736298; called by muse, mutect2
- ISM1 | c.555C>T p.D185= | Silent (SNP) | VAF 39/378 reads (10%) | catalogued as rs377766422; called by muse, mutect2
- LSM4 | c.219C>T p.D73= | Silent (SNP) | VAF 41/223 reads (18%) | catalogued as rs766768563, COSV99416828; called by muse, mutect2, varscan2
- MELTF | c.1413G>A p.R471= | Silent (SNP) | VAF 46/365 reads (13%) | catalogued as COSV99585654, COSV99585831; called by muse, mutect2, varscan2
- NOD2 | c.2064C>A p.G688= | Silent (SNP) | VAF 36/255 reads (14%) | catalogued as COSV100318228; called by muse, mutect2, varscan2
- PINK1 | c.471G>C p.L157= | Silent (SNP) | VAF 55/414 reads (13%) | catalogued as COSV100387175; called by muse, mutect2, varscan2
- PSG9 | c.525C>T p.D175= | Silent (SNP) | VAF 803/2182 reads (37%) | catalogued as rs150952802, COSV52484598; called by muse, mutect2, varscan2
- PTPN6 | c.288C>T p.L96= | Silent (SNP) | VAF 60/476 reads (13%) | catalogued as COSV100016913; called by muse, varscan2
- THEMIS2 | c.687C>T p.V229= | Silent (SNP) | VAF 26/325 reads (8%) | catalogued as rs377411263; called by muse, mutect2
- TRPC4 | c.2061A>G p.E687= | Silent (SNP) | VAF 63/444 reads (14%) | catalogued as COSV100155940; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1008G>A | 3'UTR (SNP) | VAF 42/301 reads (14%) | catalogued as rs145592443; called by muse, mutect2, varscan2
